Somatic mutation profile of tumor specimen TCGA-D8-A1XA-01A (aliquot TCGA-D8-A1XA-01A-11D-A14G-09) from TCGA case TCGA-D8-A1XA, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 64.0 years (23,387 days).
Specimen TCGA-D8-A1XA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e759e3ab-982c-4890-ad37-d3685583f13f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D8-A1XA-10A (Blood Derived Normal), aliquot TCGA-D8-A1XA-10A-01D-A14G-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4e13fca5-cc40-4545-918e-9ea9f1aff8cc

The open-access MAF lists 26 somatic variants for this specimen: 20 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 12, Silent 6, Frame Shift Del 4, Nonsense Mutation 2, Frame Shift Ins 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.916C>T p.R306* | Nonsense Mutation (SNP) | VAF 37/45 reads (82%) | hotspot (GDC flag); catalogued as rs121913344, CM971506, COSV52662281, COSV52987117, COSV53852813; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AKR1C2 | c.362C>T p.S121F | Missense Mutation (SNP) | VAF 39/100 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.597); catalogued as COSV66333191; called by muse, mutect2, varscan2
- ATF1 | c.305A>G p.Y102C | Missense Mutation (SNP) | VAF 43/95 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1182459319, COSV50394716; called by muse, mutect2, varscan2
- ATP2A1 | c.868C>A p.R290S | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.415); catalogued as COSV63921131; called by muse, mutect2, varscan2
- C10orf53 | c.473G>T p.*158Lext*24 | Nonstop Mutation (SNP) | VAF 27/69 reads (39%) | catalogued as COSV65108857, COSV65109314; called by muse, mutect2, varscan2
- CENPC | c.1804G>A p.G602S | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT tolerated (0.65); PolyPhen benign (0.205); catalogued as COSV56623398, COSV56626376; called by muse, mutect2, varscan2
- DLGAP2 | c.2847G>A p.W949* | Nonsense Mutation (SNP) | VAF 8/14 reads (57%) | catalogued as COSV70098715; called by muse, mutect2, varscan2
- IFITM2 | c.131T>C p.V44A | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.816); catalogued as COSV67714678; called by muse, mutect2, varscan2
- IFRD2 | c.760G>T p.G254C | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV57113887; called by muse, mutect2, varscan2
- NEXMIF | c.3728G>A p.R1243H | Missense Mutation (SNP) | VAF 36/54 reads (67%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.007); catalogued as rs1256402686, COSV50033492; called by muse, mutect2, varscan2
- OR51I1 | c.422A>G p.N141S | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV66508009; called by muse, mutect2, varscan2
- OR5D13 | c.683T>G p.M228R | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV62333863; called by muse, mutect2, varscan2
- PRDM10 | c.200C>T p.T67M | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs772111070, COSV62603931; called by muse, mutect2
- PTGES3L-AARSD1 | c.302C>T p.S101F (on ENST00000421990 / NM_001136042.2; = p.S83F on NM_025267.3) | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.925); catalogued as COSV64183155; called by muse, mutect2, varscan2
- SHROOM2 | c.200A>G p.K67R | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.505); catalogued as rs761019672, COSV66607011; called by muse, mutect2, varscan2
- ATF4 | c.530_533del p.S177Lfs*3 | Frame Shift Del (DEL) | VAF 20/33 reads (61%) | called by mutect2, pindel, varscan2
- CRISPLD1 | c.1154_1155del p.T385Sfs*3 | Frame Shift Del (DEL) | VAF 32/127 reads (25%) | called by pindel, varscan2
- FNIP1 | c.133_149del p.I45* | Frame Shift Del (DEL) | VAF 26/42 reads (62%) | called by mutect2, pindel, varscan2
- MAP3K1 | c.4151dup p.R1385Kfs*35 | Frame Shift Ins (INS) | VAF 39/70 reads (56%) | called by mutect2, pindel, varscan2
- TRRAP | c.9199_9227del p.I3067Pfs*8 (on ENST00000359863 / NM_001244580.1; = p.I3038Pfs*8 on NM_003496.3) | Frame Shift Del (DEL) | VAF 12/40 reads (30%) | called by mutect2, pindel, varscan2
- BRD1 | c.540C>T p.A180= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs372788569; called by muse, mutect2, varscan2
- CYP2E1 | c.12C>T p.L4= | Silent (SNP) | VAF 8/14 reads (57%) | catalogued as rs758640808, COSV53313540; called by muse, varscan2
- MAP4K3 | c.1230A>G p.A410= | Silent (SNP) | VAF 43/59 reads (73%) | catalogued as rs749727519, COSV55712014, COSV55713453; called by muse, mutect2, varscan2
- SLC51A | c.654T>G p.A218= | Silent (SNP) | VAF 28/66 reads (42%) | catalogued as COSV53056768, COSV53057779; called by muse, mutect2, varscan2
- TMEM138 | c.348T>C p.L116= | Silent (SNP) | VAF 37/75 reads (49%) | catalogued as COSV53876471; called by muse, mutect2, varscan2
- ZNF317 | c.1767C>T p.S589= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as rs368381616; called by muse, mutect2, varscan2
